Somatic mutation profile of tumor specimen BA3406D (aliquot aq-BA3406D) from BEATAML1.0 case 2796, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 33.7 years (12,304 days).
Specimen BA3406D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f1eae16-b95b-4c13-bc1a-c58a73704831.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3236D (Solid Tissue Normal), aliquot aq-BA3236D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/654ace98-37a0-4718-a41a-590ad7a1a108

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA2D3 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs1414343832, COSV55560099; called by muse, mutect2, varscan2
- WT1 | c.1072_1073insT p.R358Lfs*15 | Frame Shift Ins (INS) | VAF 19/66 reads (29%) | catalogued as COSV60067090, COSV60071392, COSV60071611, COSV60074238, COSV60075116, COSV60086039, COSV99070053; called by mutect2, varscan2
